Somatic mutation profile of tumor specimen TCGA-BJ-A290-01A (aliquot TCGA-BJ-A290-01A-11D-A17V-08) from TCGA case TCGA-BJ-A290, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 70.6 years (25,803 days).
Specimen TCGA-BJ-A290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e95d7e4-1231-4ebf-b6ca-1479c2077bd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A290-10A (Blood Derived Normal), aliquot TCGA-BJ-A290-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cee67d0a-cb87-4040-afb3-5cd6d7cdd1e5

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 16, Silent 10, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGMO | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV61108773, COSV61124600; called by muse, mutect2, varscan2
- ARSI | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.915); catalogued as rs185169618; called by muse, mutect2, varscan2
- COL6A2 | c.2818G>A p.A940T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs780703127, COSV52424290; called by muse, mutect2, varscan2
- COL6A3 | c.3927G>T p.Q1309H | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV55084241; called by muse, mutect2, varscan2
- GRIN2D | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV54377795; called by muse, mutect2
- IL11RA | c.940A>C p.T314P | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52404691; called by muse, mutect2, varscan2
- IL7R | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57405848, COSV57407051, COSV57413960; called by muse, mutect2, varscan2
- KBTBD8 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.584); catalogued as COSV55127676; called by muse, mutect2
- MAP3K3 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62280141; called by muse, mutect2, varscan2
- PLCL1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs201197388; called by muse, mutect2, varscan2
- RIT2 | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); catalogued as COSV56296431; called by muse, mutect2, varscan2
- SHROOM1 | c.2530C>T p.Q844* (on ENST00000378679 / NM_001172700.2; = p.Q839* on NM_133456.2) | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV60580824; called by muse, mutect2, varscan2
- SIGLEC6 | c.941_943del p.E314del | In Frame Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs769501549; called by pindel, varscan2
- STAB2 | c.4034G>T p.C1345F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66336727; called by muse, mutect2, varscan2
- STEAP2 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV55289880; called by muse, mutect2, varscan2
- TEK | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764269402, COSV66227441; called by muse, mutect2, varscan2
- TTC37 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62454174; called by muse, varscan2
- NAALADL1 | c.106del p.A36Pfs*102 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- H1-4 | c.90G>C p.A30= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV56800325; called by muse, mutect2, varscan2
- HELZ2 | c.2238G>A p.T746= (on ENST00000467148 / NM_001037335.2; = p.T177= on NM_033405.3) | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs777659473, COSV64409312; called by muse, mutect2, varscan2
- JARID2 | c.3321C>T p.S1107= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs765541977, COSV59187221; called by muse, mutect2, varscan2
- KRTAP5-11 | c.57C>T p.S19= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs373629079; called by muse, mutect2, varscan2
- LRTM2 | c.1005C>T p.Y335= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs750674817, COSV54564397; called by muse, mutect2, varscan2
- OR8G1 | c.639C>A p.T213= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV58380307; called by muse, mutect2, varscan2
- TG | c.84C>T p.A28= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV55070277; called by muse, mutect2, varscan2
- TRIM7 | c.1182G>A p.S394= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs773773428, COSV51241205, COSV99220143; called by mutect2, varscan2
- UMOD | c.1311C>T p.T437= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs748219272, COSV56774511; called by muse, mutect2, varscan2
- ZIC1 | c.159G>A p.S53= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1281947816, COSV51552051; called by muse, mutect2, varscan2
